CCDI case PBBUXS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4c2056ee-a589-4bf1-97f1-376ad3039995

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 4.2 years (1,531 days).

Biospecimens (3 samples)
- Sample 0DHQDI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHQEA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHQFG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
